Somatic mutation profile of tumor specimen 0DS4LB from CCDI case PBCHLM, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Alveolar rhabdomyosarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of trunk, NOS; Age at diagnosis: 12.0 years (4,379 days).
Specimen 0DS4LB: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 34d59a2c-c15c-4cfe-9287-f26682b96845.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DS4MM (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c8ef7438-486f-4988-a5a5-038a10a9c4e4

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLT3 | c.1774G>A p.V592I | Missense Mutation (SNP) | VAF 37/539 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs773466203, COSV54050958; called by muse, mutect2
- PAXBP1 | c.203C>G p.T68S | Missense Mutation (SNP) | VAF 100/220 reads (45%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0); called by muse, varscan2
- CWF19L1 | c.505-74A>G | Intron (SNP) | VAF 6/53 reads (11%) | called by muse, varscan2
